Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACM, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACM-01A (Primary Tumor).

[page 1 of 3]
CLINICAL DIAGNOSIS: HCC

Specimen : liver

Gross Photo

GROSS:

1. Specimen:

Liver: 17.0 x 12.0 x 4.5 cm, 262.5 gm (unfixed)

2. Tumor location: left

Tumor number: three

Tumor size: 1.5 x 1.5 x 1.2 cm, 1.8 x 1.5 x 1.5 cm, 1.3 x 1.2 x 1.2 cm

Distance to resection margin: 1.8 cm

3. Satellite nodule: no

4. Gross type

HCC: expanding nodular

5. Tumor necrosis: yes (10 %)

6. Hemorrhage/peliosis: no

7. Portal vein invasion: no

8. Bile duct invasion: no

ICD O-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
JAS 5/19/14

Gross photo present.

Blocks

T1-6, tumor mass and surrounding parenchyme x 6

RM, resection margin x 1

L, remaining parenchyme x 1

MICROSCOPIC:

1. Hepatocellular carcinoma: yes

1-1. Differentiation

The worst differentiation III

The major differentiation III

1-2. Histologic type: trabecular

1-3. Cell type: hepatic

1-4. Fatty change: no

2. Fibrous capsule formation: partial capsule

3. Capsular infiltration: yes

4. Septum formation: yes

5. Surgical resection margin invasion: no, margin of the clearance (1.8 cm)

6. Serosal invasion: Glisson's capsule

7. Portal vein invasion: no

[page 2 of 3]
8. Bile duct invasion: no
9. Multicentric occurrence: yes

Non-tumor liver pathology

1. Chronic hepatitis: yes
1-1. Etiology: HBV
1-2. Grade, lobular: minimal
1-3. Grade, portoperiportal: mild
1-4. Stage (fibrosis): periportal to septal
1-5. Cirrhosis: no
2. Dysplastic nodule: no
3. Ductal epithelial dysplasia: no
4. Other liver diseases: no

SPECIAL STAIN: Trichrome stain shows septal fibrosis.

NOT reported. Gross:

NOT reported. Gross:

NOT reported. Gross:

Liver, needle, Hepatocellular carcinoma , cholangiocytic differentiation

Liver, ectomy, suggestive of, hepatocellular carcinoma, chronic hepatitis, precirrhotic fibrosis
Gallbladder, ectomy, chronic cholecystitis
Lymph node, biosy, no tumor

Skin, wrist, biopsy, chronic dermatitis

Liver, ectomy, hepatocellular carcinoma
T56000, P10, M81703

[page 3 of 3]
DIAGNOSIS:

Liver, left, lobectomy:

Hepatocellular carcinoma, multiple (#3)

Suggestion :

Source: NCI Genomic Data Commons file f4bad295-5f0e-4440-9ecf-2bd6d8d0582b (TCGA-DD-AACM.ADABA595-4FA3-4D34-BB61-6B1EB345331C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).